Somatic mutation profile of tumor specimen ASCProject_0201_T2_WES (aliquot ASCProject_0201_T2_WES_1) from CMI case ASCProject_0201, project CMI-ASC: Count Me In (CMI): The Angiosarcoma (ASC) Project. Sex at birth: female; Primary diagnosis: Angiosarcoma; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 36.1 years (13,183 days).
Specimen ASCProject_0201_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6e35694a-fecf-49ad-8c39-1156e9632f85.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ASCProject_0201_SALIVA (Saliva), aliquot ASCProject_0201_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dcea9e89-9401-4c31-9dae-4d4aadbcea6f

The open-access MAF lists 26 somatic variants for this specimen: 22 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 2, Intron 1, Nonsense Mutation 1, Frame Shift Del 1, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHUK | c.1654C>T p.R552C | Missense Mutation (SNP) | VAF 50/307 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs184250593; called by muse, mutect2, varscan2
- COL4A2 | c.4679G>A p.R1560Q | Missense Mutation (SNP) | VAF 31/203 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1411209661; called by muse, mutect2, varscan2
- EIF2S3B | c.172G>A p.V58I | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1258669895; called by muse, mutect2, varscan2
- MARCHF10 | c.1421C>T p.A474V | Missense Mutation (SNP) | VAF 26/181 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100248029; called by muse, mutect2, varscan2
- NIM1K | c.670G>A p.G224S | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.06); catalogued as rs1383861226; called by muse, mutect2, varscan2
- SLC35F6 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as rs999986156, COSV100733770, COSV60426995; called by muse, mutect2
- SMTNL1 | c.1075G>A p.E359K (on ENST00000399154; = p.E396K on NM_001105565.2) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.342); catalogued as rs555332890, COSV67699590; called by mutect2, varscan2
- TOR4A | c.76G>A p.V26M | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.353); catalogued as rs1192865203, COSV62626634; called by muse, mutect2
- ACAT2 | c.1042_1055del p.A348Pfs*64 | Frame Shift Del (DEL) | VAF 18/97 reads (19%) | called by mutect2, pindel, varscan2
- AP002495.1 | c.400G>C p.G134R (on ENST00000528511; = p.G65R on NM_001375848.1) | Missense Mutation (SNP) | VAF 43/290 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.274); called by muse, mutect2, varscan2
- ATP2A1 | c.287T>C p.L96S | Missense Mutation (SNP) | VAF 59/319 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.386); called by muse, varscan2
- CELSR2 | c.7237C>A p.R2413S | Missense Mutation (SNP) | VAF 21/151 reads (14%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- CMTM8 | c.277A>G p.T93A | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- CNTN1 | c.2147G>C p.G716A | Missense Mutation (SNP) | VAF 61/291 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LPA | c.5584T>G p.C1862G | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- N4BP3 | c.761C>G p.S254C | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- NLRC3 | c.424A>T p.I142F | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.322); called by mutect2, varscan2
- PRR30 | c.1033G>T p.A345S | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- PTPN7 | c.547G>C p.V183L (on ENST00000495688; = p.V222L on NM_002832.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/182 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- PTPRB | c.2370_2371dup p.V791Efs*36 | Frame Shift Ins (INS) | VAF 40/257 reads (16%) | called by mutect2, pindel, varscan2
- TENM2 | c.6231C>A p.Y2077* (on ENST00000518659 / NM_001122679.2; = p.Y1838* on NM_001080428.3) | Nonsense Mutation (SNP) | VAF 16/131 reads (12%) | called by muse, mutect2, varscan2
- WIPF3 | c.788C>T p.P263L | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.716); called by muse, mutect2, varscan2
- SLC35D3 | c.618C>T p.F206= | Silent (SNP) | VAF 4/35 reads (11%) | called by muse, mutect2, varscan2
- ZNF711 | c.1227A>G p.L409= | Silent (SNP) | VAF 6/93 reads (6%) | called by muse, mutect2
- CNGA1 | c.-15+10412A>G | Intron (SNP) | VAF 6/46 reads (13%) | catalogued as rs1393881531, COSV62054954; called by mutect2, varscan2
- SHROOM4 | c.*1151A>T | 3'UTR (SNP) | VAF 12/198 reads (6%) | catalogued as rs895852465; called by muse, mutect2
